Gene-level copy-number profile of tumor specimen TCGA-C9-A480-01A from TCGA case TCGA-C9-A480, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 45.4 years (16,567 days).
Specimen TCGA-C9-A480-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.ebd9488f-5ae7-49c7-813d-308b00ec5f05.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C9-A480-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b596e9e-3b24-46ce-87de-e5b2bc5bc8f4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,383; copy number 4: 49,177; copy number 6: 4,713; copy number 7: 114; copy number 8: 27; copy number 9: 360; copy number 10: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C9-A480-01A-12D-A24C-01): tumor purity 0.37, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 405 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:48,026,672–49,851,059, 45 genes, copy number 10 (within-gene range 6–10): ZBTB7C, AC105101.1, AC105101.2, RNU6-708P, C18orf12, RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1, AC100778.1, AC100778.4, PRR13P4, C18orf32, RPL17-C18orf32, AC100778.2, AC100778.3, MIR1539, RPL17, SNORD58C, SNORD58A, SNORD58B, SRP72P1, LINC02837, LIPG, SMUG1P1, AC090227.3, ACAA2, AC090227.2, SNHG22, SCARNA17, AC090227.1.
- chr22:17,787,649–18,024,561, 1 gene, copy number 9 (within-gene range 4–9): MICAL3.
- chr22:17,980,868–22,923,034, 359 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
